Gene-level copy-number profile of tumor specimen TCGA-02-0037-01A from TCGA case TCGA-02-0037, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 74.1 years (27,063 days).
Specimen TCGA-02-0037-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-GBM.ea80f53e-489d-48ac-b33e-c7c08de1cd6e.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-02-0037-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/0c267b9a-f25c-48da-86a7-bf04211217fe

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 24; copy number 1: 2,613; copy number 2: 47,864; copy number 3: 9,154; copy number 4: 15; copy number 6: 64; copy number 7: 63; copy number 10: 21.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-02-0037-01): tumor purity 0.83, ploidy 2.1, whole-genome doublings 0 (call status: legacy_call).

Homozygous deletions (total copy number 0; autosomes only): 24 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,966,929–23,956,444, 24 genes: CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1, DMRTA1, LINC01239, AL391117.1, CLIC4P1, AC017067.1, AL357614.1, AL445623.2, SUMO2P2, AL445623.1, NOP56P2, ELAVL2, AL161628.1, AL365204.1, AL365204.2, AL365204.3.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 148 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:53,927,499–53,928,138, 1 gene, copy number 6: AC105384.2.
- chr8:60,046,755–60,516,795, 5 genes, copy number 6 (within-gene range 3–6): AC021393.1, SLC2A13P1, CA8, LINC01301, PDCL3P1.
- chr8:60,808,735–60,966,557, 5 genes, copy number 7 (within-gene range 3–7): AC113143.1, AC113143.2, IFITM3P8, AC022182.1, NASPP1.
- chr11:27,654,893–28,527,041, 11 genes, copy number 7 (within-gene range 2–7): BDNF, AC103796.1, CBX3P1, HSP90AA2P, AC090159.1, KIF18A, MIR610, METTL15, ATP5MGP8, RN7SKP158, AC104978.1.
- chr11:28,702,607–29,064,322, 2 genes, copy number 6 (within-gene range 2–6): LINC02742, OR2BH1P.
- chr11:29,335,878–36,232,136, 122 genes, copy number 6–10 (broad region; genes not listed).
- chr11:37,702,125–37,726,456, 2 genes, copy number 6: AC061997.1, RPL7AP56.

Autosomal genes at a single copy (total copy number 1): 2,613. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
